Somatic mutation profile of tumor specimen 1a10c200-3895-4648-b951-94f99f (aliquot 1a10c200-3895-4648-b951-94f99f_D6) from CPTAC case 01OV017, project CPTAC-2 (Ovary — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC.
Specimen 1a10c200-3895-4648-b951-94f99f: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 46a741f5-53a2-4265-8b8c-1a4c0dd9e140.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen cd0c6f13-08d2-4a74-846b-3872e0 (Blood Derived Normal), aliquot cd0c6f13-08d2-4a74-846b-3872e0_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/823a483a-a449-4374-8227-35518569aa3d

The open-access MAF lists 96 somatic variants for this specimen: 66 protein-altering or splice-affecting, 16 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 16, Nonsense Mutation 6, Intron 6, 5'UTR 4, Splice Site 4, In Frame Del 4, 3'UTR 3, Frame Shift Del 3, Splice Region 2, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRB1 | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 101/119 reads (85%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs1474376888; called by muse, mutect2, varscan2
- ARRDC4 | c.1219G>A p.D407N | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs140102944; called by muse, mutect2, varscan2
- C9orf131 | c.1922C>T p.P641L | Missense Mutation (SNP) | VAF 141/377 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as rs1345641636; called by muse, mutect2, varscan2
- CWH43 | c.791G>A p.W264* | Nonsense Mutation (SNP) | VAF 33/230 reads (14%) | catalogued as COSV56940366; called by muse, mutect2, varscan2
- DNAH2 | c.9187G>A p.V3063I | Missense Mutation (SNP) | VAF 69/91 reads (76%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.864); catalogued as rs761601410, COSV101209508; called by muse, mutect2, varscan2
- GOLGA6C | c.2032C>T p.P678S | Missense Mutation (SNP) | VAF 113/234 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1397173941; called by muse, mutect2, varscan2
- OR5L1 | c.309G>T p.L103F | Missense Mutation (SNP) | VAF 71/361 reads (20%) | SIFT tolerated (0.78); PolyPhen benign (0.144); catalogued as COSV100450085; called by muse, mutect2, varscan2
- PCK1 | c.1382G>A p.R461K | Missense Mutation (SNP) | VAF 85/223 reads (38%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.464); catalogued as rs1348451524; called by muse, mutect2, varscan2
- PFKL | c.1048G>C p.E350Q | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.017); catalogued as COSV62464331; called by muse, mutect2
- RC3H2 | c.1991G>A p.R664Q | Missense Mutation (SNP) | VAF 319/652 reads (49%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.885); catalogued as rs368997718; called by muse, mutect2, varscan2
- TGFB2 | c.338C>T p.P113L | Missense Mutation (SNP) | VAF 50/139 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.219); catalogued as rs1057524627; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TNK2 | c.1449C>T p.D483= | Splice Region (SNP) | VAF 39/371 reads (11%) | catalogued as rs200116122; called by muse, mutect2, varscan2
- TRIM55 | c.223C>T p.R75* | Nonsense Mutation (SNP) | VAF 93/253 reads (37%) | catalogued as rs750201649, COSV52545400; called by muse, mutect2, varscan2
- TTC30A | c.1696C>T p.R566* | Nonsense Mutation (SNP) | VAF 43/144 reads (30%) | catalogued as rs1390126692; called by muse, mutect2, varscan2
- UBXN11 | c.625G>T p.E209* (on ENST00000374221 / NM_183008.2; = p.E176* on NM_145345.2) | Nonsense Mutation (SNP) | VAF 138/220 reads (63%) | catalogued as COSV54625570; called by muse, mutect2, varscan2
- VAT1L | c.941C>T p.A314V | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.657); catalogued as rs764373444, COSV56816049, COSV56817510; called by muse, mutect2, varscan2
- XIRP1 | c.5028G>T p.Q1676H | Missense Mutation (SNP) | VAF 146/407 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs367702095; called by muse, mutect2, varscan2
- AC245033.1 | c.382-5C>T | Splice Region (SNP) | VAF 16/57 reads (28%) | called by muse, mutect2, varscan2
- AGRN | c.899G>A p.R300H | Missense Mutation (SNP) | VAF 94/133 reads (71%) | SIFT deleterious (0.04); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- ARL6IP1 | c.124G>C p.A42P | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- BCOR | c.4858C>A p.P1620T (on ENST00000378444 / NM_001123385.2; = p.P1586T on NM_017745.6) | Missense Mutation (SNP) | VAF 68/385 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- BUD13 | c.1647C>G p.I549M | Missense Mutation (SNP) | VAF 48/126 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- C11orf95 | c.153G>T p.Q51H | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.038); called by muse, mutect2
- C1QC | c.700dup p.D234Gfs*? (on ENST00000374637 / NM_001347619.2; = p.D234Gfs*76 on NM_172369.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 120/215 reads (56%) | called by mutect2, pindel, varscan2
- C1QL2 | c.325G>T p.G109C | Missense Mutation (SNP) | VAF 48/115 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- CDH23 | c.9910G>A p.D3304N | Missense Mutation (SNP) | VAF 156/354 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CNGA4 | c.545G>A p.W182* | Nonsense Mutation (SNP) | VAF 213/552 reads (39%) | called by muse, mutect2, varscan2
- CNTN5 | c.2315-1G>A p.X772_splice | Splice Site (SNP) | VAF 130/231 reads (56%) | called by muse, mutect2, varscan2
- COL3A1 | c.868C>T p.P290S | Missense Mutation (SNP) | VAF 57/145 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- COL3A1 | c.1035_1043del p.S346_G348del | In Frame Del (DEL) | VAF 89/239 reads (37%) | called by mutect2, pindel, varscan2
- ERN2 | c.2315C>A p.A772D | Missense Mutation (SNP) | VAF 63/119 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GAD2 | c.1380_1386+5del p.X460_splice | Splice Site (DEL) | VAF 36/104 reads (35%) | called by mutect2, pindel, varscan2
- HSP90B1 | c.769G>T p.D257Y | Missense Mutation (SNP) | VAF 114/319 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HSPBAP1 | c.261T>G p.F87L | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- IGHV3-72 | c.91G>C p.V31L | Missense Mutation (SNP) | VAF 85/445 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- ITGAX | c.1114A>G p.S372G | Missense Mutation (SNP) | VAF 53/271 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- KCNQ5 | c.454C>T p.H152Y | Missense Mutation (SNP) | VAF 55/167 reads (33%) | SIFT tolerated (0.6); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- KMO | c.711G>T p.L237F | Missense Mutation (SNP) | VAF 33/167 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KMT2C | c.13871T>G p.V4624G | Missense Mutation (SNP) | VAF 59/167 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KRT6C | c.1492G>T p.G498C | Missense Mutation (SNP) | VAF 292/735 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- MAGEB5 | c.95C>A p.T32N | Missense Mutation (SNP) | VAF 46/200 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- MBNL1 | c.1053_1067del p.A353_A357del (on ENST00000282486 / NM_207293.2; = p.A347_A351del on NM_021038.5 and 10 other RefSeq transcripts) | In Frame Del (DEL) | VAF 67/317 reads (21%) | called by mutect2, pindel, varscan2
- MDM4 | c.54G>T p.R18S | Missense Mutation (SNP) | VAF 40/137 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- MUC16 | c.7124A>C p.N2375T | Missense Mutation (SNP) | VAF 61/322 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.859); called by mutect2, varscan2
- NTSR2 | c.1187T>A p.M396K | Missense Mutation (SNP) | VAF 52/118 reads (44%) | SIFT tolerated (0.34); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- OTOG | c.4160T>A p.V1387E | Missense Mutation (SNP) | VAF 90/258 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PITPNM2 | c.499A>T p.T167S | Missense Mutation (SNP) | VAF 191/520 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- POLR2B | c.1763G>C p.R588T | Missense Mutation (SNP) | VAF 19/170 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.477); called by mutect2, varscan2
- PRPF38B | c.433G>T p.V145L | Missense Mutation (SNP) | VAF 20/228 reads (9%) | SIFT tolerated (0.52); PolyPhen benign (0.14); called by muse, mutect2
- R3HDM1 | c.2945-2A>G p.X982_splice | Splice Site (SNP) | VAF 38/99 reads (38%) | called by muse, mutect2, varscan2
- RASGEF1B | c.-6-5_6del | Splice Site (DEL) | VAF 30/102 reads (29%) | called by mutect2, pindel, varscan2
- SBF1 | c.4441_4443del p.K1481del | In Frame Del (DEL) | VAF 38/179 reads (21%) | called by mutect2, pindel, varscan2
- SLC27A1 | c.1246G>C p.V416L | Missense Mutation (SNP) | VAF 50/203 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- SLITRK3 | c.654_666del p.D218Efs*3 | Frame Shift Del (DEL) | VAF 80/642 reads (12%) | called by mutect2, pindel, varscan2
- SPHKAP | c.2534G>T p.S845I | Missense Mutation (SNP) | VAF 114/262 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0); called by mutect2, varscan2
- SRP68 | c.106G>T p.E36* | Nonsense Mutation (SNP) | VAF 22/214 reads (10%) | called by muse, mutect2
- TEKT2 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 373/1021 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- THUMPD2 | c.315G>C p.W105C | Missense Mutation (SNP) | VAF 9/122 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.534); called by muse, mutect2
- TNNT3 | c.419A>G p.E140G (on ENST00000397301 / NM_001367846.1; = p.E129G on NM_006757.4) | Missense Mutation (SNP) | VAF 158/892 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TNS2 | c.150G>T p.K50N (on ENST00000314250 / NM_170754.4; = p.K60N on NM_015319.2) | Missense Mutation (SNP) | VAF 88/232 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- TP53 | c.267_277del p.S90Vfs*55 | Frame Shift Del (DEL) | VAF 97/153 reads (63%) | called by mutect2, pindel, varscan2
- TUBA1B | c.716C>T p.T239I | Missense Mutation (SNP) | VAF 205/647 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- UPF1 | c.1595C>G p.A532G (on ENST00000599848 / NM_001297549.2; = p.A521G on NM_002911.4) | Missense Mutation (SNP) | VAF 71/158 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- WDFY4 | c.5365_5401del p.A1789Sfs*26 | Frame Shift Del (DEL) | VAF 71/201 reads (35%) | called by mutect2, pindel, varscan2
- ZNF469 | c.1004_1021del p.L335_G340del | In Frame Del (DEL) | VAF 137/423 reads (32%) | called by mutect2, pindel, varscan2
- ZNF469 | c.8849G>A p.C2950Y (on ENST00000437464; = p.C2978Y on NM_001367624.2) | Missense Mutation (SNP) | VAF 150/389 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- BPIFB2 | c.300G>A p.K100= | Silent (SNP) | VAF 92/217 reads (42%) | catalogued as rs774436795; called by muse, mutect2, varscan2
- CHRM4 | c.1371C>T p.N457= | Silent (SNP) | VAF 109/269 reads (41%) | catalogued as rs772700324, COSV100551358; called by muse, mutect2, varscan2
- ENPP3 | c.2379A>C p.T793= | Silent (SNP) | VAF 42/187 reads (22%) | called by muse, mutect2, varscan2
- FASN | c.2409G>C p.L803= | Silent (SNP) | VAF 328/1165 reads (28%) | called by muse, mutect2, varscan2
- FLG2 | c.1698C>A p.G566= | Silent (SNP) | VAF 128/336 reads (38%) | catalogued as COSV66168545; called by mutect2, varscan2
- GDPD3 | c.54C>G p.L18= | Silent (SNP) | VAF 72/196 reads (37%) | called by muse, mutect2, varscan2
- KLHL20 | c.181C>T p.L61= | Silent (SNP) | VAF 110/316 reads (35%) | catalogued as COSV52939934; called by muse, mutect2, varscan2
- KRT14 | c.1392C>T p.H464= | Silent (SNP) | VAF 66/244 reads (27%) | catalogued as rs554420514, COSV51421409; called by muse, mutect2, varscan2
- LZTS1 | c.717G>T p.L239= | Silent (SNP) | VAF 204/321 reads (64%) | called by mutect2, varscan2
- PITPNM2 | c.498G>A p.K166= | Silent (SNP) | VAF 198/603 reads (33%) | called by muse, varscan2
- RBM28 | c.1956C>G p.T652= | Silent (SNP) | VAF 165/508 reads (32%) | called by muse, mutect2, varscan2
- SPDYE3 | c.66C>G p.P22= | Silent (SNP) | VAF 85/218 reads (39%) | called by muse, mutect2, varscan2
- SPHK2 | c.1695G>A p.L565= | Silent (SNP) | VAF 14/336 reads (4%) | called by muse, mutect2
- TNXB | c.3672C>T p.L1224= (on ENST00000647633; = p.L977= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 133/345 reads (39%) | called by muse, mutect2, varscan2
- UPF3A | c.199C>T p.L67= | Silent (SNP) | VAF 228/258 reads (88%) | called by muse, varscan2
- ZNF595 | c.375G>C p.V125= | Silent (SNP) | VAF 42/407 reads (10%) | called by muse, mutect2, varscan2
- AIFM1 | c.968-36G>A | Intron (SNP) | VAF 141/370 reads (38%) | called by muse, mutect2, varscan2
- CAPN12 | c.1626+31G>T | Intron (SNP) | VAF 102/154 reads (66%) | called by muse, mutect2, varscan2
- CBFA2T3 | c.151+36361C>T | Intron (SNP) | VAF 13/36 reads (36%) | called by muse, mutect2, varscan2
- CISD1 | c.-53G>T | 5'UTR (SNP) | VAF 77/210 reads (37%) | catalogued as COSV100445741; called by muse, mutect2, varscan2
- FHL1 | c.*910_*921del | 3'UTR (DEL) | VAF 137/350 reads (39%) | called by mutect2, pindel, varscan2
- H3-2 | c.*47C>A | 3'UTR (SNP) | VAF 109/402 reads (27%) | catalogued as rs184512298; called by muse, varscan2
- IGHMBP2 | c.1236-34G>A | Intron (SNP) | VAF 160/389 reads (41%) | catalogued as rs1226154875; called by muse, mutect2, varscan2
- RBM43 | c.3+322C>G | Intron (SNP) | VAF 66/382 reads (17%) | called by mutect2, varscan2
- RPS3 | c.-2A>G | 5'UTR (SNP) | VAF 132/474 reads (28%) | catalogued as rs773735949; called by muse, mutect2, varscan2
- SNRPB | c.-27G>C | 5'UTR (SNP) | VAF 46/155 reads (30%) | catalogued as COSV60016349; called by muse, mutect2, varscan2
- SP5 | chr2:170714420 A>T | 5'Flank (SNP) | VAF 24/46 reads (52%) | catalogued as rs1191618431; called by muse, mutect2, varscan2
- TPCN1 | c.-125-1420C>A | Intron (SNP) | VAF 86/225 reads (38%) | called by muse, mutect2, varscan2
- TTLL7 | c.-318C>A | 5'UTR (SNP) | VAF 138/442 reads (31%) | called by muse, mutect2, varscan2
- XAGE5 | c.*35T>G | 3'UTR (SNP) | VAF 101/226 reads (45%) | called by muse, mutect2, varscan2
